Somatic mutation profile of tumor specimen C3N-03425-05 (aliquot CPT0245830006) from CPTAC case C3N-03425, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 64.5 years (23,574 days).
Specimen C3N-03425-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd451402-83b3-49ce-9939-8fbca0dc5876.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03425-31 (Blood Derived Normal), aliquot CPT0245870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7ca2771-c81b-43ea-9bd8-3140dc33e17f

The open-access MAF lists 556 somatic variants for this specimen: 378 protein-altering or splice-affecting, 123 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 319, Silent 123, Nonsense Mutation 34, Intron 23, RNA 15, Splice Region 9, 3'UTR 7, Frame Shift Del 7, 5'UTR 6, Splice Site 3, 5'Flank 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 155/560 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADAC | c.694T>C p.Y232H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.042); catalogued as rs763690818; called by muse, mutect2, varscan2
- ADAM23 | c.2482C>T p.Q828* | Nonsense Mutation (SNP) | VAF 15/298 reads (5%) | catalogued as COSV52227975; called by muse, mutect2
- ADAT1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57186550; called by muse, mutect2
- ADCK5 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 154/408 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782000623; called by muse, mutect2, varscan2
- AEBP2 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV56866095; called by muse, mutect2
- AHI1 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV55630224; called by muse, mutect2, varscan2
- AK4 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs774903218; called by muse, mutect2, varscan2
- ANKRD30BL | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as rs1373864021, COSV99724656; called by muse, mutect2, varscan2
- ANKRD49 | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100120005; called by muse, mutect2, varscan2
- AP3M2 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs755233870; called by muse, mutect2, varscan2
- APBA2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 70/621 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs780907005; called by muse, mutect2, varscan2
- APOL3 | c.463G>C p.E155Q (on ENST00000349314 / NM_145640.2; = p.E84Q on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/335 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.749); catalogued as COSV62580829; called by muse, mutect2
- ARHGAP35 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 18/270 reads (7%) | catalogued as COSV101350595; called by muse, mutect2
- ARID3A | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 69/413 reads (17%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs765015703; called by muse, mutect2, varscan2
- ARR3 | c.440G>A p.C147Y | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs1295817238; called by muse, mutect2
- ASB12 | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs751170404; called by muse, mutect2, varscan2
- ATF7IP | c.3355C>T p.Q1119* | Nonsense Mutation (SNP) | VAF 19/221 reads (9%) | catalogued as COSV53769782; called by muse, mutect2
- ATP6V1A | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0.017); catalogued as rs775322278, COSV99850143; called by muse, mutect2
- ATXN1 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374338186; called by muse, mutect2, varscan2
- BAP1 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 71/444 reads (16%) | catalogued as COSV56233960; called by muse, mutect2, varscan2
- BNC1 | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61756535; called by muse, mutect2, varscan2
- BOD1L1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs781753047; called by muse, mutect2, varscan2
- CACNA2D4 | c.2568G>A p.M856I | Missense Mutation (SNP) | VAF 46/445 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1385257290; called by muse, mutect2
- CBX1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as COSV99848218; called by muse, mutect2, varscan2
- CCDC28A | c.421C>G p.P141A | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV99082011; called by muse, mutect2, varscan2
- CD163 | c.1693G>C p.G565R | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV63135893; called by muse, mutect2, varscan2
- CD34 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768640209, COSV100178078; called by muse, mutect2
- CDX1 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140956520, COSV51567579; called by muse, mutect2, varscan2
- CENPT | c.1002G>C p.E334D | Missense Mutation (SNP) | VAF 81/494 reads (16%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.828); catalogued as rs1469428944; called by muse, varscan2
- CEP20 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 73/409 reads (18%) | catalogued as COSV55383924; called by muse, mutect2, varscan2
- CHM | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198760905, COSV63301306; called by muse, mutect2, varscan2
- CLEC14A | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 42/235 reads (18%) | catalogued as COSV60562119; called by muse, mutect2, varscan2
- CNTNAP1 | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 10/159 reads (6%) | catalogued as rs1034847479; called by muse, mutect2
- CNTNAP1 | c.2849C>G p.S950C | Missense Mutation (SNP) | VAF 41/516 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs748092457, COSV52853091; called by muse, mutect2
- CORO7 | c.79C>G p.R27G | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as rs753411850; called by muse, mutect2, varscan2
- CPNE5 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs375462904; called by muse, mutect2, varscan2
- CRB1 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.397); catalogued as rs868022034; called by muse, mutect2
- CUBN | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 63/616 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.06); catalogued as COSV64712849; called by muse, mutect2, varscan2
- DACT3 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.72); catalogued as rs924479727; called by mutect2, varscan2
- DCSTAMP | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV99886903, COSV99886906; called by muse, mutect2, varscan2
- DDX42 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 45/431 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs938122231; called by muse, mutect2, varscan2
- DISP1 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs765644354, COSV52665697; called by muse, mutect2, varscan2
- DNAJC5G | c.113+1G>A p.X38_splice | Splice Site (SNP) | VAF 16/192 reads (8%) | catalogued as rs762007084; called by muse, mutect2
- DRP2 | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV100871740, COSV100872065; called by muse, mutect2, varscan2
- EDEM2 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs375264450; called by muse, mutect2, varscan2
- EDN3 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 51/473 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV61110251; called by muse, mutect2, varscan2
- ELOA2 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 102/492 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1215564684, COSV99796280; called by muse, mutect2, varscan2
- EPPK1 | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs921902664, COSV73261229; called by muse, mutect2, varscan2
- ERMAP | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV60275416; called by muse, mutect2, varscan2
- ERVW-1 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.683); catalogued as rs572996090, COSV101423828; called by muse, varscan2
- F13B | c.1312C>G p.R438G | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.186); catalogued as COSV66373444; called by muse, mutect2, varscan2
- FAT3 | c.10732C>G p.Q3578E | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV53184245, COSV53185215; called by muse, mutect2, varscan2
- FAT3 | c.12697C>T p.R4233C | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760262852, COSV53100646, COSV53100654; called by muse, mutect2
- FBN2 | c.7576G>A p.D2526N | Missense Mutation (SNP) | VAF 51/441 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV52524899; called by muse, mutect2, varscan2
- FBN3 | c.7034C>T p.S2345F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV54465072; called by muse, mutect2
- FBXO41 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99721796; called by muse, mutect2, varscan2
- FBXW10 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 85/284 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1325256416; called by muse, mutect2, varscan2
- FGD6 | c.2758C>G p.Q920E | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV100676824; called by muse, mutect2
- FOXG1 | c.552C>G p.F184L | Missense Mutation (SNP) | VAF 11/339 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57399493; called by muse, mutect2
- FRYL | c.8498G>A p.R2833Q | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.02); catalogued as rs776349108, COSV99977419; called by muse, mutect2, varscan2
- GABPA | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs751844857, COSV61396811; called by muse, mutect2, varscan2
- GCC2 | c.4309G>A p.E1437K | Missense Mutation (SNP) | VAF 38/524 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766656471; called by muse, mutect2
- GPR149 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV67669357; called by muse, mutect2
- GRIA4 | c.1268T>C p.M423T | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV56898616; called by muse, mutect2, varscan2
- GSPT1 | c.1045G>A p.D349N (on ENST00000420576 / NM_001130007.2; = p.D487N on NM_002094.4) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.447); catalogued as rs1437462264; called by muse, mutect2, varscan2
- GUCY1A1 | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV56653453; called by muse, mutect2, varscan2
- GYS2 | c.1656C>G p.I552M | Missense Mutation (SNP) | VAF 33/376 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53921019, COSV53930228; called by muse, mutect2
- H2AC4 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 83/417 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52517894; called by muse, mutect2, varscan2
- H3C2 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 54/503 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV52517865, COSV52518608, COSV52520327; called by muse, mutect2, varscan2
- H4C2 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV55140712; called by muse, mutect2, varscan2
- HPN | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs147827161; called by muse, mutect2
- HSPA12B | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs746188452; called by muse, mutect2, varscan2
- IFT88 | c.1796C>T p.S599F (on ENST00000319980 / NM_001318493.2; = p.S590F on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.276); catalogued as COSV60676809; called by muse, mutect2
- IGF1R | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs768636512, COSV51332283; called by muse, mutect2, varscan2
- IGSF9 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 100/387 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0.107); catalogued as COSV63642388; called by muse, mutect2, varscan2
- IL10RA | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs766027945; called by muse, mutect2, varscan2
- ISYNA1 | c.830A>G p.N277S | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs140705791; called by muse, mutect2, varscan2
- KCNK5 | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV63989423; called by muse, varscan2
- KLF5 | c.338G>C p.R113T | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs745752404; called by muse, varscan2
- KRTAP19-2 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 74/386 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.851); catalogued as rs141067359; called by muse, mutect2, varscan2
- MAGEE1 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 123/512 reads (24%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV63909308; called by muse, mutect2, varscan2
- MAMLD1 | c.2023G>T p.V675L | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as COSV53372117; called by muse, mutect2, varscan2
- MEP1A | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.446); catalogued as rs764569906, COSV57919023; called by muse, mutect2, varscan2
- METTL27 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.854); catalogued as rs782005704, COSV99936434; called by muse, mutect2
- MGAM | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1554453330; called by muse, mutect2, varscan2
- MLXIPL | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1554602980; called by muse, mutect2, varscan2
- MMUT | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM099603; called by muse, mutect2, varscan2
- MOS | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 53/427 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.428); catalogued as rs758253167; called by muse, mutect2, varscan2
- MT2A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 66/329 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs368767847; called by muse, mutect2, varscan2
- MTNR1A | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 44/352 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs866777247; called by muse, mutect2
- MUC16 | c.40320C>G p.F13440L | Missense Mutation (SNP) | VAF 22/281 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.454); catalogued as COSV66690504; called by muse, mutect2
- MUC16 | c.32765C>A p.P10922Q | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV67456192; called by muse, mutect2, varscan2
- MUC16 | c.26618C>G p.S8873C | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV67447627; called by muse, mutect2
- MUC16 | c.16001C>T p.S5334F | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67450102, COSV67500098; called by muse, mutect2
- MUC5B | c.15214G>C p.E5072Q | Missense Mutation (SNP) | VAF 44/366 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV71591090; called by muse, mutect2, varscan2
- MYCBP2 | c.13529G>A p.R4510K (on ENST00000357337; = p.R4548K on NM_015057.5) | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62011225, COSV62029534; called by muse, mutect2, varscan2
- MYO18B | c.4725G>C p.K1575N | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs1250288213, COSV59130533; called by muse, mutect2, varscan2
- NFE2L2 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV67962008; called by muse, mutect2, varscan2
- NR4A2 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 64/752 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771391809; called by muse, mutect2
- NT5C1B | c.1094G>A p.R365K (on ENST00000359846 / NM_001199086.2; = p.R305K on NM_033253.4) | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as rs1377555339; called by muse, mutect2, varscan2
- PCDH8 | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV100131832; called by muse, mutect2, varscan2
- PCDH9 | c.3604G>A p.E1202K (on ENST00000377865 / NM_203487.3; = p.E1168K on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/363 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as COSV60582032; called by muse, mutect2
- PCK1 | c.1776C>G p.I592M | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as rs1054922986, COSV60128950; called by muse, mutect2
- PDGFRB | c.2586C>T p.S862= | Splice Region (SNP) | VAF 18/136 reads (13%) | catalogued as rs201662789; called by muse, mutect2
- PEG3 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV55638749; called by muse, mutect2, varscan2
- PEX14 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 65/518 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.089); catalogued as rs903736101, COSV100750273; called by muse, mutect2, varscan2
- PHKA1 | c.2101T>A p.S701T | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.755); catalogued as COSV59809471; called by muse, mutect2
- PLXND1 | c.4337C>T p.S1446L | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1217331466; called by muse, mutect2
- PRDM16 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.411); catalogued as COSV54591118; called by muse, mutect2, varscan2
- PRDM9 | c.1570G>T p.V524F | Missense Mutation (SNP) | VAF 22/638 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV99691114; called by muse, mutect2
- PREPL | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs776058554, COSV53215152; called by muse, mutect2
- PRKCI | c.1772C>G p.S591C | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55522552; called by muse, mutect2
- PRKD1 | c.1317G>A p.R439= | Splice Region (SNP) | VAF 17/237 reads (7%) | catalogued as COSV59587815; called by muse, mutect2
- PROZ | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as rs985660395, COSV61438907; called by muse, mutect2
- PRR32 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as COSV64420948; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1484A>T p.Y495F (on ENST00000352766; = p.Y416F on NM_181334.5) | Missense Mutation (SNP) | VAF 68/304 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100424173; called by muse, mutect2, varscan2
- PRSS36 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs951361732; called by muse, mutect2, varscan2
- PTGDR | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 37/429 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV100035546; called by muse, mutect2
- PTGIR | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 124/387 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs200590943, COSV52191577; called by muse, mutect2, varscan2
- RALGAPB | c.1796C>G p.S599* | Nonsense Mutation (SNP) | VAF 18/170 reads (11%) | catalogued as COSV53439139; called by muse, mutect2, varscan2
- RASGRF1 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV69184047; called by muse, mutect2
- RBM47 | c.1762G>A p.D588N (on ENST00000295971 / NM_001098634.2; = p.D519N on NM_019027.4) | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs769388482, COSV55943459; called by muse, mutect2
- RBMS1 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs1415096029; called by muse, mutect2
- RBPJL | c.1077G>A p.W359* | Nonsense Mutation (SNP) | VAF 15/196 reads (8%) | catalogued as COSV100643404; called by muse, mutect2
- RECK | c.2837G>A p.R946K | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs762679837; called by muse, mutect2
- RNF187 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 52/160 reads (33%) | catalogued as COSV59959857, COSV59960193; called by muse, varscan2
- SACS | c.13002G>C p.L4334F | Missense Mutation (SNP) | VAF 31/362 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66539680; called by muse, mutect2
- SAMD7 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 73/272 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs868523081; called by muse, mutect2, varscan2
- SAMD9L | c.3728G>A p.R1243K | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59085607; called by muse, mutect2, varscan2
- SCAMP1 | c.846C>G p.F282L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV57239747; called by muse, mutect2
- SCN3A | c.3256G>A p.D1086N | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs149911613; called by muse, mutect2, varscan2
- SH3BP4 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as rs773132376, COSV60645847; called by muse, mutect2, varscan2
- SKIDA1 | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV71611015; called by muse, mutect2, varscan2
- SLC39A12 | c.2016G>C p.L672F (on ENST00000377369 / NM_001145195.2; = p.L635F on NM_152725.3) | Missense Mutation (SNP) | VAF 23/285 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV66202015, COSV66203026; called by muse, mutect2
- SLC6A14 | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 34/195 reads (17%) | catalogued as COSV64147768; called by muse, mutect2, varscan2
- SLCO4C1 | c.1063C>G p.Q355E | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV60516042; called by muse, mutect2
- SSU72P8 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV66361121; called by muse, mutect2, varscan2
- STK31 | c.2827C>T p.L943= | Splice Region (SNP) | VAF 6/66 reads (9%) | catalogued as COSV63457481; called by muse, mutect2
- STRADB | c.1114-1G>A p.X372_splice | Splice Site (SNP) | VAF 46/308 reads (15%) | catalogued as rs1178170999; called by muse, mutect2, varscan2
- SULT1C4 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.144); catalogued as COSV99731912; called by muse, mutect2
- TBC1D4 | c.1630A>G p.I544V | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs981446160; called by muse, mutect2, varscan2
- TDRD7 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 97/314 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768158623; called by muse, mutect2, varscan2
- TECRL | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 31/141 reads (22%) | catalogued as rs377068257; called by muse, mutect2, varscan2
- TET1 | c.2804A>G p.Y935C | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs367630351; called by muse, mutect2
- TIAM2 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs763216069; called by muse, mutect2, varscan2
- TLE4 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV54642452; called by muse, mutect2, varscan2
- TMEM109 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.511); catalogued as COSV50003100; called by muse, mutect2, varscan2
- TMEM126B | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.642); catalogued as COSV62670694; called by muse, mutect2, varscan2
- TMEM151A | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 75/429 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1248743169, COSV59173118; called by muse, mutect2, varscan2
- TMEM63C | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.021); catalogued as rs753694690; called by muse, mutect2, varscan2
- TUBGCP2 | c.945G>T p.R315S | Missense Mutation (SNP) | VAF 73/333 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV53306773; called by muse, mutect2, varscan2
- TUT4 | c.1982G>C p.R661T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV57116631; called by muse, mutect2
- TXNDC2 | c.773C>T p.S258L (on ENST00000306084 / NM_001098529.2; = p.S191L on NM_032243.6) | Missense Mutation (SNP) | VAF 91/400 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as rs1286963395; called by muse, varscan2
- USF3 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57075457; called by muse, mutect2
- USO1 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1178724674; called by muse, mutect2
- USP8 | c.221A>G p.K74R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs756495148; called by muse, mutect2
- WDR62 | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 54/526 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); catalogued as rs762605299; called by muse, mutect2, varscan2
- WSCD2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs768459005, COSV54584594; called by muse, mutect2
- XIRP2 | c.1376C>T p.S459F (on ENST00000628543; = p.S634F on NM_152381.6) | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99745283; called by muse, mutect2
- YME1L1 | c.1834G>C p.D612H (on ENST00000326799 / NM_139312.3; = p.D555H on NM_014263.4) | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as COSV100463153, COSV100463934; called by muse, mutect2, varscan2
- ZNF705A | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 36/421 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs771661939; called by muse, mutect2
- ZNF768 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs189981520; called by muse, mutect2, varscan2
- ZNHIT3 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.091); catalogued as rs774224518; called by muse, mutect2
- ABCA13 | c.7279C>G p.L2427V | Missense Mutation (SNP) | VAF 56/544 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2
- ABCA13 | c.11377G>T p.A3793S | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ADAM32 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 22/193 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- ADGRG2 | c.1391C>A p.T464N (on ENST00000379869 / NM_001079858.3; = p.T461N on NM_005756.4) | Missense Mutation (SNP) | VAF 14/303 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.075); called by muse, mutect2
- AHNAK | c.16711G>A p.D5571N | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2
- ANGPT1 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.034); called by muse, mutect2
- ANKRD49 | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, varscan2
- APBA2 | c.1204A>T p.S402C | Missense Mutation (SNP) | VAF 60/573 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ARHGAP17 | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP23 | c.4388C>T p.S1463L | Missense Mutation (SNP) | VAF 37/328 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ARHGAP35 | c.1328C>G p.S443C | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.341); called by muse, mutect2
- ARHGEF12 | c.4375C>G p.Q1459E | Missense Mutation (SNP) | VAF 72/666 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP7A | c.130del p.E44Kfs*41 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- ATP7A | c.4457C>T p.S1486L | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP8A1 | c.2855C>T p.S952L | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- BBS9 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BICDL1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2
- BIRC6 | c.3929C>G p.S1310* | Nonsense Mutation (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- BRCC3 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- BTN1A1 | c.1363C>A p.P455T | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C16orf78 | c.379G>T p.G127C | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- CA10 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- CA9 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- CACNA1A | c.5630G>C p.R1877T | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2
- CASP8 | c.1172G>T p.R391I (on ENST00000432109 / NM_033355.3; = p.R408I on NM_001228.4) | Missense Mutation (SNP) | VAF 33/439 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2
- CBY1 | c.315dup p.T106Hfs*3 | Frame Shift Ins (INS) | VAF 40/242 reads (17%) | called by mutect2, pindel, varscan2
- CC2D1B | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- CCDC144A | c.183G>C p.E61D | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC168 | c.17408C>A p.A5803E | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- CCDC180 | c.4004C>A p.T1335N | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CDH22 | c.1015del p.I339Sfs*3 | Frame Shift Del (DEL) | VAF 30/186 reads (16%) | called by mutect2, pindel
- CDHR5 | c.1420G>C p.E474Q (on ENST00000358353 / NM_001171968.2; = p.E480Q on NM_021924.5) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); called by muse, mutect2
- CDHR5 | c.1070G>C p.R357T | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK12 | c.2836G>C p.E946Q | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CDPF1 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- CEACAM5 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.263); called by muse, mutect2
- CEP290 | c.1876A>G p.S626G | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLPX | c.425C>G p.S142* | Nonsense Mutation (SNP) | VAF 11/159 reads (7%) | called by muse, mutect2
- CNTD1 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.2456C>A p.S819* | Nonsense Mutation (SNP) | VAF 24/209 reads (11%) | called by muse, mutect2
- COL25A1 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- COL3A1 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 176/475 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- CSAG1 | c.168-4C>G | Splice Region (SNP) | VAF 36/301 reads (12%) | called by muse, mutect2, varscan2
- CSDE1 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CSE1L | c.1011G>C p.Q337H | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); called by muse, mutect2
- CTNNA3 | c.1405A>G p.R469G | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2
- CTNND2 | c.2716G>T p.D906Y | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTSL | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CUBN | c.10171C>G p.Q3391E | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CYLC1 | c.1235A>G p.E412G | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); called by muse, mutect2
- CYLC1 | c.1724C>A p.S575* | Nonsense Mutation (SNP) | VAF 24/247 reads (10%) | called by muse, mutect2, varscan2
- DBNL | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DCAF16 | c.11G>T p.R4I | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, varscan2
- DCDC1 | c.5170G>C p.E1724Q (on ENST00000597505 / NM_001367979.1; = p.E831Q on NM_020869.3) | Missense Mutation (SNP) | VAF 15/279 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.929); called by muse, mutect2
- DCP1B | c.319+3G>C | Splice Region (SNP) | VAF 33/324 reads (10%) | called by muse, mutect2, varscan2
- DLG1 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- DMXL2 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DOCK6 | c.1149C>G p.F383L | Missense Mutation (SNP) | VAF 73/294 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DYNC1H1 | c.11167G>A p.D3723N | Missense Mutation (SNP) | VAF 35/353 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DYNC2H1 | c.12494C>G p.S4165C | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- EDC4 | c.1165A>G p.T389A | Missense Mutation (SNP) | VAF 71/337 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- EFCAB13 | c.2494+7G>C | Splice Region (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- EHMT2 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ENKUR | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- EPB41 | c.922C>T p.Q308* (on ENST00000343067 / NM_001166005.2; = p.Q99* on NM_004437.4) | Nonsense Mutation (SNP) | VAF 30/320 reads (9%) | called by muse, mutect2
- EPRS1 | c.2809C>T p.Q937* | Nonsense Mutation (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2
- ERVV-2 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- EXOG | c.209_212del p.T70Kfs*33 | Frame Shift Del (DEL) | VAF 37/156 reads (24%) | called by mutect2, pindel, varscan2
- FAM184A | c.785A>T p.E262V | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM184A | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- FCRL2 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- FGF18 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 65/428 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- FMN2 | c.2125C>T p.Q709* | Nonsense Mutation (SNP) | VAF 97/437 reads (22%) | called by muse, mutect2, varscan2
- FOXE1 | c.503C>A p.A168E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.431); called by mutect2, varscan2
- FZD8 | c.966C>G p.F322L | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.048); called by muse, mutect2
- GADL1 | c.943C>A p.R315S | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- GAPVD1 | c.3308C>T p.S1103F (on ENST00000394104; = p.S1112F on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- GAS2L2 | c.2557G>C p.E853Q | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.476); called by muse, mutect2
- GRN | c.425T>C p.M142T | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- HERC1 | c.4558G>C p.E1520Q | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- HRNR | c.2818C>G p.Q940E | Missense Mutation (SNP) | VAF 207/729 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IDO1 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IFT172 | c.1670G>C p.R557T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- IKBKB | c.860A>G p.Q287R | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- INTU | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQGAP1 | c.2189C>G p.S730C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- IRGQ | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 32/482 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2
- IRS2 | c.873G>C p.M291I | Missense Mutation (SNP) | VAF 79/532 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ITPRIP | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- KCNA2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- KCNA3 | c.118T>A p.Y40N | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.021); called by muse, varscan2
- KDM4D | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 21/277 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- KDM5C | c.3779C>T p.A1260V | Missense Mutation (SNP) | VAF 55/471 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- KLF5 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 78/337 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.135); called by muse, varscan2
- KRT6B | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 160/1373 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRT6C | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- LAMC3 | c.479A>T p.Y160F | Missense Mutation (SNP) | VAF 130/458 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- LANCL3 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 92/426 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LARGE1 | c.878G>C p.R293T | Missense Mutation (SNP) | VAF 46/512 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- LIPK | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2
- LONRF3 | c.1216C>T p.P406S (on ENST00000371628 / NM_001031855.3; = p.P365S on NM_024778.5) | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- LPA | c.4271C>T p.P1424L | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- LYAR | c.831A>T p.E277D | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.864); called by muse, mutect2
- LYAR | c.830A>T p.E277V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- MAOA | c.1377C>G p.V459= | Splice Region (SNP) | VAF 34/376 reads (9%) | called by muse, mutect2
- METTL3 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- MGAM2 | c.6098C>A p.T2033K | Missense Mutation (SNP) | VAF 80/229 reads (35%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- MINDY2 | c.1828G>C p.E610Q | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MRGPRX4 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRPL23 | c.321C>A p.F107L | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC1 | c.3746C>G p.S1249C (on ENST00000611571 / NM_001371720.1; = p.S260C on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.41874C>G p.H13958Q | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MUC16 | c.36519C>G p.I12173M | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- MYH11 | c.1268C>A p.A423D | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO10 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO9B | c.998+5G>C | Splice Region (SNP) | VAF 40/146 reads (27%) | called by muse, mutect2, varscan2
- MYPN | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NACAD | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- NEDD4 | c.2455C>G p.Q819E (on ENST00000508342 / NM_001284338.1; = p.Q400E on NM_006154.4) | Missense Mutation (SNP) | VAF 58/398 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NOSTRIN | c.772G>C p.E258Q (on ENST00000317647 / NM_001039724.4; = p.E180Q on NM_052946.3) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- NPRL2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRXN3 | c.2113G>A p.E705K (on ENST00000335750 / NM_001330195.2; = p.E332K on NM_004796.6) | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OLFM1 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); called by muse, mutect2
- OLFM4 | c.769_770insTGG p.P257delinsLA | In Frame Ins (INS) | VAF 18/104 reads (17%) | called by mutect2, pindel*, varscan2
- OPHN1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.566); called by muse, mutect2
- OR2Y1 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.702); called by muse, mutect2
- OR5H15 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR7G3 | c.937T>A p.*313Rext*? | Nonstop Mutation (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- OSBP2 | c.772T>G p.S258A | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- OXCT1 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- PC | c.2788_2791del p.E930Pfs*38 | Frame Shift Del (DEL) | VAF 63/304 reads (21%) | called by mutect2, pindel, varscan2
- PEX26 | c.327T>G p.Y109* | Nonsense Mutation (SNP) | VAF 177/647 reads (27%) | called by muse, mutect2, varscan2
- PGM2 | c.1744G>C p.E582Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PHKA2 | c.2026T>A p.Y676N | Missense Mutation (SNP) | VAF 99/386 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C2G | c.3752T>A p.I1251N (on ENST00000676171; = p.I1210N on NM_004570.5) | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PIKFYVE | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PJA1 | c.701G>T p.S234I | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); called by mutect2, varscan2
- POF1B | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 39/167 reads (23%) | called by muse, mutect2, varscan2
- POLG2 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 11/300 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); called by muse, mutect2
- POU2F1 | c.1917_1918del p.Q640Sfs*14 (on ENST00000541643 / NM_001365848.1; = p.Q663Sfs*14 on NM_002697.4) | Frame Shift Del (DEL) | VAF 71/293 reads (24%) | called by mutect2, pindel, varscan2
- PRAMEF4 | c.1323G>A p.M441I | Missense Mutation (SNP) | VAF 49/522 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PROB1 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PROX1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2
- PSMD4 | c.963+3G>A | Splice Region (SNP) | VAF 32/308 reads (10%) | called by muse, mutect2, varscan2
- PTEN | c.260_264del p.Q87Pfs*3 | Frame Shift Del (DEL) | VAF 39/215 reads (18%) | called by mutect2, pindel, varscan2
- PTPRR | c.1881-1G>A p.X627_splice | Splice Site (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- RANBP2 | c.8630C>A p.A2877E | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAPSN | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 38/357 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RASAL3 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RGS21 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPL13A | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- RTL9 | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SAMD9 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- SAMD9L | c.2306dup p.N769Kfs*5 | Frame Shift Ins (INS) | VAF 35/153 reads (23%) | called by mutect2, pindel, varscan2
- SAP30BP | c.44C>G p.A15G | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SETMAR | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SH2D4A | c.1054C>G p.L352V | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.655); called by muse, mutect2
- SHANK1 | c.2786C>T p.P929L | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SHQ1 | c.446G>C p.G149A | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIRT3 | c.625A>T p.T209S | Missense Mutation (SNP) | VAF 36/327 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC7A2 | c.350G>A p.W117* (on ENST00000494857 / NM_001370338.1; = p.W157* on NM_003046.6) | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- SLFN12L | c.436C>T p.L146F (on ENST00000260908 / NM_001363830.1; = p.L164F on NM_001195790.1) | Missense Mutation (SNP) | VAF 25/307 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLIT1 | c.2646G>C p.K882N | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- SNRNP200 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 55/362 reads (15%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.3928G>T p.G1310W | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPATA31D1 | c.3929G>A p.G1310E | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SPIB | c.75C>G p.D25E | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2
- SPINK2 | c.207C>G p.I69M | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); called by muse, mutect2
- SSH2 | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 31/458 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); called by muse, mutect2
- SSH2 | c.2041G>C p.G681R | Missense Mutation (SNP) | VAF 31/458 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2
- STRA8 | c.410G>A p.G137E (on ENST00000275764; = p.G115E on NM_182489.2) | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STS | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 44/368 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SYAP1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 90/345 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYN1 | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.16813C>G p.Q5605E (on ENST00000367255 / NM_182961.4; = p.Q5534E on NM_033071.3) | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TCP10L2 | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TEX14 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- TIAM1 | c.2552C>G p.S851* | Nonsense Mutation (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- TMED1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TMEM150C | c.361C>G p.Q121E | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TMEM232 | c.434del p.L145Yfs*19 | Frame Shift Del (DEL) | VAF 40/220 reads (18%) | called by mutect2, pindel, varscan2
- TMEM234 | c.68_73del p.P23_L24del | In Frame Del (DEL) | VAF 70/395 reads (18%) | called by mutect2, pindel, varscan2
- TMPRSS6 | c.1726G>C p.E576Q | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- TOGARAM1 | c.2326C>G p.H776D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TP53INP1 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- TRIM22 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.384); called by muse, mutect2
- TRIML1 | c.1307C>G p.S436C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- TRIO | c.4114T>A p.C1372S | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.85340T>C p.I28447T (on ENST00000591111; = p.I21023T on NM_003319.4) | Missense Mutation (SNP) | VAF 78/290 reads (27%) | PolyPhen benign (0.114); called by muse, mutect2, varscan2
- TTN | c.48850G>C p.E16284Q (on ENST00000591111; = p.E8860Q on NM_003319.4) | Missense Mutation (SNP) | VAF 16/132 reads (12%) | PolyPhen benign (0.227); called by muse, mutect2, varscan2
- TTN | c.38020G>C p.E12674Q (on ENST00000591111; = p.E5250Q on NM_003319.4) | Missense Mutation (SNP) | VAF 76/435 reads (17%) | PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- TTN | c.551G>C p.R184T | Missense Mutation (SNP) | VAF 19/107 reads (18%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TUBA1A | c.606C>A p.F202L | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUBB4A | c.265A>T p.N89Y | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TYRP1 | c.1174C>G p.H392D | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE3C | c.2183G>A p.R728K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- UBR4 | c.8215G>T p.E2739* | Nonsense Mutation (SNP) | VAF 18/177 reads (10%) | called by muse, mutect2
- USH2A | c.15604C>G p.L5202V | Missense Mutation (SNP) | VAF 48/423 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UTRN | c.10180G>T p.G3394* | Nonsense Mutation (SNP) | VAF 68/285 reads (24%) | called by muse, mutect2, varscan2
- VAV3 | c.2430G>C p.L810F | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VPS13C | c.1504C>T p.P502S (on ENST00000644861 / NM_020821.3; = p.P459S on NM_017684.5) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- WDR75 | c.555G>C p.K185N | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.283); called by muse, mutect2
- WNK3 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- ZMYM5 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZNF160 | c.1831C>T p.H611Y | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF180 | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 12/185 reads (6%) | called by muse, mutect2
- ZNF20 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF215 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); called by muse, mutect2
- ZNF646 | c.2098G>C p.E700Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ZNF674 | c.1303C>T p.H435Y | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ZNF782 | c.87G>C p.E29D | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF878 | c.1223C>G p.S408* | Nonsense Mutation (SNP) | VAF 30/277 reads (11%) | called by muse, mutect2, varscan2
- ZNHIT3 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2
- ABLIM1 | c.2331C>T p.L777= | Silent (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- AC011462.1 | c.759G>A p.A253= | Silent (SNP) | VAF 28/512 reads (5%) | catalogued as rs770514966; ClinVar: likely benign; called by muse, mutect2
- ADAM19 | c.2226G>A p.L742= | Silent (SNP) | VAF 28/174 reads (16%) | catalogued as rs1185728451, COSV57436904; called by muse, mutect2, varscan2
- ADCY7 | c.2493C>T p.F831= | Silent (SNP) | VAF 25/180 reads (14%) | called by muse, mutect2, varscan2
- AHNAK2 | c.8637G>A p.V2879= | Silent (SNP) | VAF 49/492 reads (10%) | catalogued as COSV100316235; called by muse, mutect2
- AKAP6 | c.4692T>C p.H1564= | Silent (SNP) | VAF 22/460 reads (5%) | called by muse, mutect2
- AKR1C4 | c.366C>T p.L122= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs782237290; called by muse, mutect2, varscan2
- AOC1 | c.36G>C p.L12= | Silent (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- AP2M1 | c.387G>A p.L129= | Silent (SNP) | VAF 24/442 reads (5%) | called by muse, mutect2
- APOA5 | c.423C>T p.A141= | Silent (SNP) | VAF 108/467 reads (23%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.1926G>A p.Q642= | Silent (SNP) | VAF 28/210 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.789C>G p.L263= | Silent (SNP) | VAF 21/321 reads (7%) | catalogued as rs764320787; called by muse, mutect2
- ATOH7 | c.333C>G p.L111= | Silent (SNP) | VAF 30/370 reads (8%) | catalogued as COSV65447593; called by muse, mutect2
- ATRX | c.5010G>A p.Q1670= | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as COSV100970132; called by muse, mutect2, varscan2
- B3GALT2 | c.906C>G p.L302= | Silent (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- BCLAF3 | c.1663C>A p.R555= | Silent (SNP) | VAF 38/157 reads (24%) | called by muse, mutect2, varscan2
- BPTF | c.8196G>A p.Q2732= | Silent (SNP) | VAF 20/354 reads (6%) | catalogued as COSV100075931; called by muse, mutect2
- BUB3 | c.837C>T p.I279= | Silent (SNP) | VAF 24/161 reads (15%) | catalogued as rs745619504; called by muse, mutect2, varscan2
- C3 | c.3342C>T p.P1114= | Silent (SNP) | VAF 41/336 reads (12%) | catalogued as COSV55581986; called by muse, mutect2, varscan2
- CAMKK2 | c.1029C>G p.L343= | Silent (SNP) | VAF 56/618 reads (9%) | catalogued as rs781497110; called by muse, mutect2
- CCNL1 | c.1425G>A p.Q475= | Silent (SNP) | VAF 40/355 reads (11%) | called by muse, mutect2, varscan2
- CCSER1 | c.1869G>C p.L623= | Silent (SNP) | VAF 80/317 reads (25%) | called by muse, varscan2
- CENPT | c.573G>A p.L191= | Silent (SNP) | VAF 29/157 reads (18%) | called by muse, mutect2
- CHD5 | c.3165C>A p.L1055= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- COL18A1 | c.2652T>C p.I884= (on ENST00000359759 / NM_130444.3; = p.I649= on NM_030582.4) | Silent (SNP) | VAF 39/314 reads (12%) | called by muse, mutect2, varscan2
- DCX | c.171C>T p.F57= | Silent (SNP) | VAF 49/335 reads (15%) | called by muse, mutect2, varscan2
- DIAPH2 | c.1923C>T p.I641= | Silent (SNP) | VAF 25/187 reads (13%) | called by muse, mutect2, varscan2
- DNMT1 | c.2502C>T p.V834= | Silent (SNP) | VAF 44/476 reads (9%) | called by muse, mutect2
- DUS4L-BCAP29 | c.1281G>C p.L427= | Silent (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- EIF4G2 | c.1821C>G p.L607= | Silent (SNP) | VAF 43/175 reads (25%) | called by muse, mutect2, varscan2
- ELK1 | c.1092G>T p.P364= | Silent (SNP) | VAF 50/194 reads (26%) | called by muse, mutect2, varscan2
- EPB41L3 | c.2916G>A p.T972= | Silent (SNP) | VAF 36/358 reads (10%) | catalogued as rs527779795, COSV59450068; called by muse, mutect2
- FAM160A1 | c.759C>G p.L253= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs1160956034; called by muse, mutect2, varscan2
- FAM98A | c.651C>T p.V217= | Silent (SNP) | VAF 15/253 reads (6%) | called by muse, mutect2
- FANCB | c.273C>T p.L91= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs768094187; called by muse, varscan2
- FBXO32 | c.402C>T p.L134= | Silent (SNP) | VAF 13/133 reads (10%) | called by muse, mutect2, varscan2
- FERMT3 | c.798G>A p.V266= | Silent (SNP) | VAF 27/262 reads (10%) | called by muse, mutect2
- FMR1NB | c.408G>C p.L136= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as COSV100789544; called by muse, mutect2
- FRY | c.2013C>T p.L671= | Silent (SNP) | VAF 35/208 reads (17%) | catalogued as COSV66573074; called by muse, mutect2, varscan2
- GLDC | c.2601G>C p.T867= | Silent (SNP) | VAF 40/353 reads (11%) | catalogued as rs371678175; called by muse, mutect2, varscan2
- GLT6D1 | c.126C>G p.R42= | Silent (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- GPR156 | c.924C>T p.F308= | Silent (SNP) | VAF 32/226 reads (14%) | called by muse, mutect2, varscan2
- HEPH | c.609C>T p.L203= (on ENST00000343002; = p.L257= on NM_138737.5) | Silent (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2
- HNRNPF | c.936C>T p.L312= | Silent (SNP) | VAF 22/368 reads (6%) | catalogued as rs879548216; called by muse, mutect2
- IGF2R | c.7464C>G p.L2488= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- IRS4 | c.1290C>A p.A430= | Silent (SNP) | VAF 95/655 reads (15%) | catalogued as COSV64534401; called by muse, mutect2, varscan2
- KCNF1 | c.891C>T p.I297= | Silent (SNP) | VAF 30/310 reads (10%) | catalogued as rs559871658, COSV54462612; called by muse, mutect2
- KLF5 | c.288G>A p.L96= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as COSV66615629; called by muse, varscan2
- KLHL41 | c.918C>T p.I306= | Silent (SNP) | VAF 32/334 reads (10%) | catalogued as rs1243564552; called by muse, mutect2
- KSR2 | c.1449A>G p.L483= | Silent (SNP) | VAF 64/298 reads (21%) | catalogued as rs1270581941; called by muse, varscan2
- LRP1 | c.5223G>A p.Q1741= | Silent (SNP) | VAF 56/268 reads (21%) | called by muse, mutect2, varscan2
- MAN1C1 | c.918G>A p.V306= | Silent (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- MAZ | c.804G>C p.T268= | Silent (SNP) | VAF 52/258 reads (20%) | called by muse, mutect2, varscan2
- MFSD6 | c.1698G>A p.L566= | Silent (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2, varscan2
- MKS1 | c.30C>T p.T10= | Silent (SNP) | VAF 98/446 reads (22%) | catalogued as rs576239597; called by muse, mutect2, varscan2
- MMP16 | c.1203G>C p.G401= | Silent (SNP) | VAF 49/146 reads (34%) | catalogued as COSV54152797; called by muse, mutect2, varscan2
- MRGPRX4 | c.183C>T p.V61= | Silent (SNP) | VAF 22/162 reads (14%) | called by muse, mutect2
- MTR | c.243C>T p.I81= | Silent (SNP) | VAF 37/271 reads (14%) | called by muse, mutect2, varscan2
- MUC4 | c.5241C>T p.V1747= | Silent (SNP) | VAF 59/1136 reads (5%) | called by muse, mutect2
- MUC5B | c.2838C>A p.T946= | Silent (SNP) | VAF 40/302 reads (13%) | called by muse, mutect2, varscan2
- NAV3 | c.183C>G p.T61= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- NDN | c.576C>A p.L192= | Silent (SNP) | VAF 56/238 reads (24%) | called by muse, mutect2, varscan2
- NEDD4L | c.2580G>T p.V860= (on ENST00000400345 / NM_001144967.3; = p.V840= on NM_015277.6) | Silent (SNP) | VAF 43/154 reads (28%) | called by muse, mutect2, varscan2
- NFATC1 | c.2232C>T p.L744= | Silent (SNP) | VAF 32/359 reads (9%) | catalogued as rs954133868, COSV53696365; called by muse, mutect2
- NKAIN1 | c.468G>A p.L156= | Silent (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- NKX2-8 | c.285G>A p.Q95= | Silent (SNP) | VAF 211/523 reads (40%) | catalogued as rs368998134; called by muse, mutect2, varscan2
- NLGN3 | c.1824G>A p.L608= (on ENST00000358741 / NM_181303.2; = p.L588= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/379 reads (8%) | called by muse, mutect2
- NLRP7 | c.2649G>A p.Q883= (on ENST00000340844 / NM_206828.3; = p.Q855= on NM_139176.3) | Silent (SNP) | VAF 23/255 reads (9%) | called by muse, mutect2
- NOL9 | c.1746G>A p.K582= | Silent (SNP) | VAF 14/185 reads (8%) | called by muse, mutect2
- ONECUT3 | c.510C>G p.L170= | Silent (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- OR2C3 | c.63A>G p.R21= | Silent (SNP) | VAF 20/184 reads (11%) | catalogued as COSV100825631; called by muse, mutect2
- OR51D1 | c.702C>T p.I234= | Silent (SNP) | VAF 87/484 reads (18%) | catalogued as COSV62914224; called by muse, mutect2, varscan2
- OR5A2 | c.321G>C p.G107= | Silent (SNP) | VAF 24/135 reads (18%) | called by muse, mutect2, varscan2
- OR8D2 | c.189C>T p.L63= | Silent (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- P2RY14 | c.117C>G p.L39= | Silent (SNP) | VAF 91/295 reads (31%) | called by muse, mutect2, varscan2
- PANX2 | c.606G>A p.E202= | Silent (SNP) | VAF 19/191 reads (10%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1566G>A p.P522= | Silent (SNP) | VAF 158/1062 reads (15%) | catalogued as rs782199558, COSV65324982; called by muse, mutect2, varscan2
- PCDHB4 | c.540C>T p.L180= | Silent (SNP) | VAF 55/271 reads (20%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.1737G>C p.L579= | Silent (SNP) | VAF 49/369 reads (13%) | called by muse, mutect2, varscan2
- PCNT | c.4462C>A p.R1488= | Silent (SNP) | VAF 121/507 reads (24%) | catalogued as COSV64027159; called by muse, mutect2, varscan2
- PDGFRB | c.474G>A p.V158= | Silent (SNP) | VAF 27/329 reads (8%) | called by muse, mutect2
- PEG3 | c.2982G>A p.E994= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- POM121C | c.48G>C p.P16= | Silent (SNP) | VAF 52/446 reads (12%) | catalogued as rs1349278029; called by muse, mutect2, varscan2
- POM121L2 | c.1587T>A p.S529= | Silent (SNP) | VAF 25/318 reads (8%) | called by muse, mutect2
- POU3F3 | c.210C>G p.V70= | Silent (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- PRDM5 | c.1071C>T p.F357= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as rs1257146262, COSV53360931; called by muse, mutect2, varscan2
- PTGFRN | c.1662G>A p.A554= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs576756226, COSV67798722; called by muse, mutect2, varscan2
- PTPRO | c.3582G>T p.L1194= (on ENST00000281171 / NM_030667.3; = p.L1166= on NM_002848.4) | Silent (SNP) | VAF 32/348 reads (9%) | called by muse, mutect2
- RAI14 | c.2208G>A p.V736= | Silent (SNP) | VAF 13/196 reads (7%) | called by muse, mutect2
- RAP1GAP | c.1458G>T p.T486= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as rs747561632, COSV51572748; called by muse, mutect2
- RASGRP4 | c.1638C>G p.V546= | Silent (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- REL | c.1701C>T p.F567= | Silent (SNP) | VAF 21/202 reads (10%) | called by muse, mutect2, varscan2
- RFX4 | c.1209C>A p.T403= (on ENST00000392842 / NM_213594.3; = p.T309= on NM_032491.6) | Silent (SNP) | VAF 40/226 reads (18%) | catalogued as COSV99986080; called by muse, mutect2, varscan2
- RORA | c.123G>T p.P41= | Silent (SNP) | VAF 80/363 reads (22%) | called by muse, mutect2, varscan2
- RPS6KL1 | c.411C>T p.L137= | Silent (SNP) | VAF 24/217 reads (11%) | called by muse, mutect2
- RYR1 | c.4566C>A p.A1522= | Silent (SNP) | VAF 168/602 reads (28%) | called by muse, mutect2, varscan2
- RYR2 | c.1749A>T p.P583= | Silent (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2, varscan2
- SAGE1 | c.978G>A p.L326= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- SALL3 | c.2364G>A p.K788= | Silent (SNP) | VAF 27/285 reads (9%) | called by muse, mutect2
- SCFD2 | c.537G>A p.L179= | Silent (SNP) | VAF 46/178 reads (26%) | called by muse, mutect2, varscan2
- SEMA6A | c.1215C>T p.I405= | Silent (SNP) | VAF 25/202 reads (12%) | called by muse, mutect2, varscan2
- SLC12A7 | c.465C>T p.L155= | Silent (SNP) | VAF 28/362 reads (8%) | called by muse, mutect2
- SLC13A3 | c.1659G>C p.L553= | Silent (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2
- SLC15A4 | c.336C>G p.L112= | Silent (SNP) | VAF 36/337 reads (11%) | called by muse, mutect2, varscan2
- SLC23A2 | c.435C>T p.F145= | Silent (SNP) | VAF 22/240 reads (9%) | called by muse, mutect2
- SLC25A13 | c.927G>A p.Q309= | Silent (SNP) | VAF 46/704 reads (7%) | called by muse, mutect2
- SLC25A2 | c.279G>A p.R93= | Silent (SNP) | VAF 12/448 reads (3%) | catalogued as COSV53404119; called by muse, mutect2
- SLC35F1 | c.573C>G p.V191= | Silent (SNP) | VAF 22/236 reads (9%) | called by muse, mutect2
- SLC3A1 | c.1695C>G p.L565= | Silent (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- SLITRK2 | c.1476G>T p.G492= | Silent (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- SMPD2 | c.252C>G p.V84= | Silent (SNP) | VAF 24/227 reads (11%) | catalogued as rs780721560; called by muse, mutect2, varscan2
- SUSD5 | c.342C>T p.V114= | Silent (SNP) | VAF 24/266 reads (9%) | catalogued as rs780260281; called by muse, mutect2
- TANC2 | c.2385C>T p.F795= | Silent (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2
- TEX50 | c.175C>T p.L59= | Silent (SNP) | VAF 35/338 reads (10%) | called by muse, mutect2
- THOC2 | c.1522C>T p.L508= | Silent (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- TMEM147 | c.129C>G p.L43= | Silent (SNP) | VAF 51/441 reads (12%) | called by muse, mutect2, varscan2
- TMEM229A | c.780C>T p.F260= | Silent (SNP) | VAF 16/305 reads (5%) | called by muse, mutect2
- TMEM237 | c.252G>A p.Q84= (on ENST00000409883 / NM_001044385.3; = p.Q76= on NM_152388.4) | Silent (SNP) | VAF 48/271 reads (18%) | called by muse, varscan2
- TNC | c.4704G>A p.K1568= | Silent (SNP) | VAF 89/368 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.15291G>A p.L5097= (on ENST00000591111; = p.L4170= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/153 reads (10%) | catalogued as COSV100621946; called by muse, mutect2, varscan2
- VPS52 | c.1644C>T p.L548= | Silent (SNP) | VAF 30/299 reads (10%) | called by muse, mutect2, varscan2
- ZFP14 | c.162G>C p.V54= | Silent (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2, varscan2
- ZNF732 | c.1383G>A p.L461= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as rs782244153; called by muse, varscan2
- ABCA7 | c.498+18G>C | Intron (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- AC010266.2 | n.2061C>G | RNA (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- AC024940.1 | n.1064C>T | RNA (SNP) | VAF 10/77 reads (13%) | catalogued as rs566801122; called by muse, mutect2, varscan2
- AC073648.1 | n.302C>A | RNA (SNP) | VAF 45/280 reads (16%) | called by muse, mutect2, varscan2
- AC235097.1 | n.144T>A | RNA (SNP) | VAF 22/130 reads (17%) | called by muse, mutect2, varscan2
- AC235097.1 | n.145C>A | RNA (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- ACTR3BP2 | n.752G>C | RNA (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- AKT2 | c.-84-9873G>A | Intron (SNP) | VAF 29/435 reads (7%) | called by muse, mutect2
- ALG11 | c.*82C>G | 3'UTR (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- ANXA2P2 | n.790C>T | RNA (SNP) | VAF 30/324 reads (9%) | catalogued as rs1445613963; called by muse, mutect2
- ARHGEF4 | chr2:130915626 C>A | 5'Flank (SNP) | VAF 46/276 reads (17%) | catalogued as COSV100387431; called by muse, mutect2, varscan2
- C11orf21 | c.54-135G>A | Intron (SNP) | VAF 67/326 reads (21%) | catalogued as COSV51720645; called by muse, mutect2, varscan2
- C8orf34 | c.607+19C>G | Intron (SNP) | VAF 18/96 reads (19%) | catalogued as rs1325688113, COSV61401933; called by muse, mutect2
- CLCC1 | c.-69C>T | 5'UTR (SNP) | VAF 89/387 reads (23%) | catalogued as rs887343525; called by muse, mutect2, varscan2
- CLCN6 | c.2529+160C>G | Intron (SNP) | VAF 35/232 reads (15%) | catalogued as rs565308939; called by muse, mutect2, varscan2
- CYP2A7P1 | n.662C>T | RNA (SNP) | VAF 32/150 reads (21%) | catalogued as rs752470270; called by muse, mutect2, varscan2
- CYP2A7P2 | n.77G>A | RNA (SNP) | VAF 28/298 reads (9%) | called by muse, mutect2
- CYP4F22 | c.*26G>T | 3'UTR (SNP) | VAF 20/216 reads (9%) | called by muse, mutect2
- DENND1C | c.1583+48G>C | Intron (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- DST | c.4297-2118A>T | Intron (SNP) | VAF 51/489 reads (10%) | called by muse, mutect2, varscan2
- FNBP1L | c.*32G>A | 3'UTR (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- IGFBP2 | c.672+56C>T | Intron (SNP) | VAF 16/133 reads (12%) | catalogued as rs1384830808; called by muse, mutect2, varscan2
- JAG1 | c.1120+15C>T | Intron (SNP) | VAF 20/137 reads (15%) | catalogued as COSV54761425; called by muse, mutect2, varscan2
- KCNIP1 | c.-6G>T | 5'UTR (SNP) | VAF 25/170 reads (15%) | called by muse, mutect2, varscan2
- KCNK12 | c.*8597C>G | 3'UTR (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- KCNU1 | c.2010-17128G>C | Intron (SNP) | VAF 56/196 reads (29%) | called by muse, mutect2, varscan2
- KIZ | chr20:21126070 G>A | 5'Flank (SNP) | VAF 25/184 reads (14%) | catalogued as rs1365049138; called by mutect2, varscan2
- KRT8P11 | n.1279G>T | RNA (SNP) | VAF 86/304 reads (28%) | called by muse, mutect2, varscan2
- LAIR1 | c.415+1405C>G | Intron (SNP) | VAF 20/203 reads (10%) | called by muse, mutect2, varscan2
- LINC01193 | n.874G>A | RNA (SNP) | VAF 22/536 reads (4%) | catalogued as rs1344017516; called by muse, mutect2
- MGAT4A | c.*2C>T | 3'UTR (SNP) | VAF 10/123 reads (8%) | called by muse, mutect2
- MUC2 | chr11:1094695 C>T | 3'Flank (SNP) | VAF 19/126 reads (15%) | catalogued as rs1218180211; called by muse, varscan2
- NPAS3 | c.558+18039A>T | Intron (SNP) | VAF 79/179 reads (44%) | called by muse, mutect2, varscan2
- OR7A2P | n.260C>T | RNA (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- PBX1 | c.265+27053C>G | Intron (SNP) | VAF 84/351 reads (24%) | catalogued as rs1278753829; called by muse, mutect2, varscan2
- PCNT | c.9700+21G>C | Intron (SNP) | VAF 12/340 reads (4%) | called by muse, mutect2
- PLSCR1 | c.*29C>T | 3'UTR (SNP) | VAF 20/143 reads (14%) | called by muse, mutect2, varscan2
- PMM2 | c.-42C>T | 5'UTR (SNP) | VAF 71/388 reads (18%) | catalogued as rs1344836955; called by muse, mutect2, varscan2
- POLE4 | c.340+25C>G | Intron (SNP) | VAF 15/116 reads (13%) | catalogued as rs749830304; called by muse, mutect2, varscan2
- PTGDS | c.115-43C>T | Intron (SNP) | VAF 29/249 reads (12%) | catalogued as rs1180904840; called by muse, mutect2, varscan2
- PTGR1 | c.652-1545C>G | Intron (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- RPL3 | c.4-497G>T | Intron (SNP) | VAF 42/276 reads (15%) | catalogued as rs777486888; called by muse, mutect2, varscan2
- RUFY2 | c.-88G>A | 5'UTR (SNP) | VAF 12/133 reads (9%) | catalogued as rs895945827; called by muse, mutect2, varscan2
- SLC6A14 | c.-5G>A | 5'UTR (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- SNORD115-33 | n.9G>A | RNA (SNP) | VAF 13/222 reads (6%) | called by muse, mutect2
- SNX14 | c.912+20G>A | Intron (SNP) | VAF 6/56 reads (11%) | catalogued as rs1378119797; called by muse, mutect2
- SYNE1 | c.16711-31C>T | Intron (SNP) | VAF 12/216 reads (6%) | catalogued as rs1386896204; called by muse, mutect2
- TFE3 | c.*11C>A | 3'UTR (SNP) | VAF 20/67 reads (30%) | catalogued as rs1225967893; called by muse, mutect2, varscan2
- TM4SF19 | c.450-70C>G | Intron (SNP) | VAF 21/281 reads (7%) | called by muse, mutect2
- TMEM147 | c.148-17C>T | Intron (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- TPM3 | c.642+599G>C | Intron (SNP) | VAF 149/632 reads (24%) | called by muse, mutect2, varscan2
- TTC3P1 | n.5633C>T | RNA (SNP) | VAF 11/280 reads (4%) | called by muse, mutect2
- VMA21 | chrX:151396957 G>T | 5'Flank (SNP) | VAF 49/267 reads (18%) | catalogued as rs1472652268; called by muse, mutect2, varscan2
- ZDHHC1 | c.-11G>A | 5'UTR (SNP) | VAF 13/255 reads (5%) | called by muse, mutect2
- ZNF286B | n.1598C>T | RNA (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
